Somatic mutation profile of tumor specimen MMRF_1426_1_BM_CD138pos (aliquot MMRF_1426_1_BM_CD138pos_T1_KAS5U_L01373) from MMRF case MMRF_1426, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 59.4 years (21,683 days).
Specimen MMRF_1426_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fc8ea711-f157-44cd-8e59-14c848819107.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1426_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1426_1_PB_Whole_C2_KAS5U_L01385; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4a51a4a0-445b-4421-83f3-0d279ef46905

The open-access MAF lists 119 somatic variants for this specimen: 44 protein-altering or splice-affecting, 22 silent, 53 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, 3'UTR 27, Silent 22, Intron 7, RNA 7, 5'UTR 6, 3'Flank 5, Nonsense Mutation 3, Frame Shift Del 1, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 117/250 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACTG1 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 97/190 reads (51%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.988); catalogued as rs375159565; called by muse, mutect2, varscan2
- ADGB | c.613-1G>T p.X205_splice | Splice Site (SNP) | VAF 10/110 reads (9%) | catalogued as rs1483269010; called by muse, mutect2
- ARSA | c.434G>T p.R145L | Missense Mutation (SNP) | VAF 46/86 reads (53%) | SIFT tolerated (0.3); PolyPhen benign (0.401); catalogued as rs551548107, COSV99332569; called by muse, mutect2, varscan2
- BRF1 | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs775546215, COSV100527164; called by muse, mutect2, varscan2
- CLRN2 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 126/263 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as rs374428888; called by muse, mutect2, varscan2
- CNOT2 | c.228C>G p.Y76* | Nonsense Mutation (SNP) | VAF 31/68 reads (46%) | catalogued as COSV57505311; called by muse, mutect2, varscan2
- DIPK1B | c.152C>T p.S51L | Missense Mutation (SNP) | VAF 63/213 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as rs746420716; called by muse, mutect2, varscan2
- DUSP2 | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs1282580603; called by muse, mutect2, varscan2
- ERO1A | c.56G>C p.S19T | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs751293420; called by muse, mutect2, varscan2
- FAM135B | c.3259G>A p.E1087K | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.272); catalogued as COSV52737945; called by muse, mutect2, varscan2
- GOLGB1 | c.9381G>T p.E3127D | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.51); PolyPhen benign (0.028); catalogued as rs762841332; called by muse, mutect2, varscan2
- GOPC | c.351A>C p.K117N | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.066); catalogued as COSV50000529, COSV50002098; called by muse, mutect2, varscan2
- HOXC8 | c.37T>C p.Y13H | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs766632582; called by muse, mutect2, varscan2
- IGHV2-70 | c.234A>T p.K78N | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs376708751; called by muse, varscan2
- IGHV2-70 | c.10C>G p.L4V | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as rs376256801; called by muse, varscan2
- IGLV3-1 | c.314A>C p.Y105S | Missense Mutation (SNP) | VAF 52/101 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs185803370; called by muse, mutect2, varscan2
- LACTBL1 | c.679C>T p.R227C (on ENST00000618559; = p.R272C on NM_001289974.2) | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.914); catalogued as rs1427121172; called by muse, mutect2, varscan2
- LIMCH1 | c.2443C>T p.R815C | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756189356, COSV58284897; called by muse, mutect2, varscan2
- NOX3 | c.553G>A p.V185I | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1335863885; called by muse, mutect2, varscan2
- RCE1 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 45/63 reads (71%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.567); catalogued as rs374360120, COSV100546983; called by muse, mutect2, varscan2
- SEMA3C | c.1411G>T p.E471* | Nonsense Mutation (SNP) | VAF 84/202 reads (42%) | catalogued as COSV54852889; called by muse, mutect2, varscan2
- TEAD1 | c.1064G>A p.R355H | Missense Mutation (SNP) | VAF 92/272 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs1176475680, COSV57563726; called by muse, mutect2, varscan2
- ABCA13 | c.14680T>G p.Y4894D | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- ALB | c.284G>C p.G95A | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.873); called by muse, mutect2
- CARD11 | c.2510G>A p.R837Q | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- CCDC121 | c.364_365del p.Q122Dfs*12 | Frame Shift Del (DEL) | VAF 53/153 reads (35%) | called by mutect2, pindel, varscan2
- CTTN | c.976G>A p.D326N | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- CYLD | c.1520A>C p.E507A | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DCLK2 | c.654A>C p.K218N | Missense Mutation (SNP) | VAF 68/128 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM172A | c.362A>T p.K121I | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- GAP43 | c.679A>T p.K227* | Nonsense Mutation (SNP) | VAF 95/275 reads (35%) | called by muse, mutect2, varscan2
- IGSF6 | c.228G>C p.E76D | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- KLRK1 | c.557A>C p.K186T | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT tolerated (0.37); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- LRFN1 | c.1565C>T p.A522V | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NGRN | c.407A>G p.Q136R | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- OAZ1 | c.196T>C p.W66R | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PCNX1 | c.2353C>T p.R785C | Missense Mutation (SNP) | VAF 10/203 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); called by muse, mutect2
- PRDM6 | c.824G>A p.G275E | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USH2A | c.4808G>A p.S1603N | Missense Mutation (SNP) | VAF 80/203 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZFAND2A | c.392A>G p.D131G | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ZNF426 | c.436T>A p.C146S | Missense Mutation (SNP) | VAF 45/331 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ZNF517 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 64/116 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- ZNF804B | c.1537G>C p.E513Q | Missense Mutation (SNP) | VAF 65/130 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- ACP3 | c.1005G>A p.T335= | Silent (SNP) | VAF 39/94 reads (41%) | catalogued as rs1004695850; called by muse, mutect2, varscan2
- ACSS1 | c.1530C>T p.I510= | Silent (SNP) | VAF 24/51 reads (47%) | catalogued as rs1211766847; called by muse, mutect2, varscan2
- ADGRL2 | c.2250C>T p.N750= (on ENST00000370717 / NM_001366005.1; = p.N737= on NM_012302.4) | Silent (SNP) | VAF 50/114 reads (44%) | catalogued as COSV54683248; called by muse, mutect2, varscan2
- BOK | c.30C>T p.F10= | Silent (SNP) | VAF 8/44 reads (18%) | called by muse, mutect2, varscan2
- BTG1 | c.117C>T p.T39= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as rs1386115649, COSV55459883; called by muse, mutect2, varscan2
- C2CD5 | c.2583T>C p.N861= | Silent (SNP) | VAF 73/190 reads (38%) | called by muse, mutect2, varscan2
- CENPF | c.6591C>T p.S2197= | Silent (SNP) | VAF 79/168 reads (47%) | called by muse, mutect2, varscan2
- COL6A3 | c.7131T>C p.C2377= | Silent (SNP) | VAF 13/107 reads (12%) | catalogued as rs768164723; called by muse, mutect2, varscan2
- CSMD1 | c.6210G>A p.S2070= (on ENST00000520002; = p.S2069= on NM_033225.6) | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs190880525, COSV59346155; called by muse, mutect2, varscan2
- CXCR2 | c.534G>A p.L178= | Silent (SNP) | VAF 19/166 reads (11%) | called by muse, mutect2, varscan2
- GJA3 | c.198C>T p.Y66= | Silent (SNP) | VAF 93/189 reads (49%) | called by muse, mutect2, varscan2
- GPRC5C | c.279G>A p.A93= (on ENST00000652232; = p.A48= on NM_018653.4) | Silent (SNP) | VAF 49/159 reads (31%) | catalogued as rs767530166; called by muse, mutect2, varscan2
- IARS2 | c.2922C>T p.S974= | Silent (SNP) | VAF 38/137 reads (28%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.351A>G p.A117= | Silent (SNP) | VAF 12/19 reads (63%) | catalogued as rs377546718; called by muse, varscan2
- IGLV3-1 | c.222A>T p.S74= | Silent (SNP) | VAF 50/100 reads (50%) | catalogued as rs185368174; called by muse, varscan2
- MAP3K14 | c.159A>T p.G53= | Silent (SNP) | VAF 57/234 reads (24%) | catalogued as COSV60923851; called by muse, mutect2, varscan2
- MBTD1 | c.1833G>A p.A611= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs370630316; called by muse, mutect2, varscan2
- METTL24 | c.270G>A p.G90= | Silent (SNP) | VAF 13/29 reads (45%) | called by muse, mutect2, varscan2
- RTN4R | c.453C>T p.R151= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs745427309; called by muse, mutect2, varscan2
- RYR3 | c.10902C>T p.S3634= (on ENST00000389232; = p.S3635= on NM_001036.6) | Silent (SNP) | VAF 54/75 reads (72%) | catalogued as rs374681133; called by muse, mutect2, varscan2
- TLR8 | c.1449A>G p.G483= (on ENST00000218032 / NM_138636.5; = p.G501= on NM_016610.4) | Silent (SNP) | VAF 13/99 reads (13%) | called by muse, mutect2, varscan2
- WNK1 | c.543G>A p.A181= | Silent (SNP) | VAF 17/29 reads (59%) | called by muse, mutect2, varscan2
- AGL | c.*1880T>C | 3'UTR (SNP) | VAF 33/127 reads (26%) | called by muse, mutect2, varscan2
- BBS12 | c.*284G>T | 3'UTR (SNP) | VAF 26/54 reads (48%) | catalogued as rs961683033; called by muse, mutect2
- BIRC8 | n.1000C>T | RNA (SNP) | VAF 10/82 reads (12%) | catalogued as rs1407089403, COSV101461315; called by muse, mutect2, varscan2
- BMP6 | c.*1147_*1183del | 3'UTR (DEL) | VAF 25/120 reads (21%) | called by mutect2, pindel
- C7orf26 | c.1149-154G>A | Intron (SNP) | VAF 17/32 reads (53%) | called by muse, mutect2, varscan2
- CADM2 | chr3:86067991 A>T | 3'Flank (SNP) | VAF 7/109 reads (6%) | called by muse, mutect2
- CCDC90B | c.*2312C>T | 3'UTR (SNP) | VAF 32/110 reads (29%) | called by muse, mutect2, varscan2
- CCN1 | c.*567G>T | 3'UTR (SNP) | VAF 22/45 reads (49%) | called by muse, mutect2, varscan2
- CDH10 | c.*536T>A | 3'UTR (SNP) | VAF 22/71 reads (31%) | catalogued as rs919923393; called by muse, mutect2, varscan2
- CFAP44 | c.*561C>T | 3'UTR (SNP) | VAF 33/121 reads (27%) | catalogued as rs879245823; called by muse, mutect2, varscan2
- CST9 | c.*897T>C | 3'UTR (SNP) | VAF 28/72 reads (39%) | called by muse, mutect2, varscan2
- CXCL16 | c.-478C>G | 5'UTR (SNP) | VAF 24/50 reads (48%) | called by muse, mutect2, varscan2
- DBX2 | c.*1437C>A | 3'UTR (SNP) | VAF 28/91 reads (31%) | called by muse, mutect2, varscan2
- DNAJC5 | c.*36G>A | 3'UTR (SNP) | VAF 48/100 reads (48%) | called by muse, mutect2, varscan2
- EFL1P1 | n.22C>T | RNA (SNP) | VAF 10/101 reads (10%) | called by muse, mutect2
- EIF1B | chr3:40309631 A>G | 5'Flank (SNP) | VAF 17/104 reads (16%) | called by muse, mutect2, varscan2
- ERGIC2 | c.*24A>C | 3'UTR (SNP) | VAF 94/221 reads (43%) | called by muse, mutect2, varscan2
- GPR37 | c.-716C>T | 5'UTR (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2, varscan2
- GRIK3 | c.*1331G>A | 3'UTR (SNP) | VAF 47/105 reads (45%) | called by muse, mutect2, varscan2
- HMGCLL1 | c.*801C>A | 3'UTR (SNP) | VAF 42/101 reads (42%) | called by muse, mutect2, varscan2
- IPO7 | c.*1709T>G | 3'UTR (SNP) | VAF 76/129 reads (59%) | called by muse, mutect2, varscan2
- IPO7 | c.*1824_*1825dup | 3'UTR (INS) | VAF 32/67 reads (48%) | called by mutect2, pindel, varscan2
- IPP | chr1:45694377 T>A | 3'Flank (SNP) | VAF 85/208 reads (41%) | called by muse, mutect2, varscan2
- KCNK5 | c.*776del | 3'UTR (DEL) | VAF 51/227 reads (22%) | called by mutect2, pindel, varscan2
- LINC01565 | n.711C>T | RNA (SNP) | VAF 40/122 reads (33%) | called by muse, mutect2
- MCF2L | chr13:113098278 G>A | 3'Flank (SNP) | VAF 58/123 reads (47%) | called by muse, mutect2, varscan2
- MIR4472-2 | n.10_12del | RNA (DEL) | VAF 8/44 reads (18%) | catalogued as rs780065289; called by pindel, varscan2
- MME | c.196+4753C>T | Intron (SNP) | VAF 13/33 reads (39%) | catalogued as rs777899848; called by muse, mutect2, varscan2
- MS4A15 | c.*498G>C | 3'UTR (SNP) | VAF 68/192 reads (35%) | called by muse, mutect2, varscan2
- NOL4L | c.110-8730G>A | Intron (SNP) | VAF 44/88 reads (50%) | called by muse, varscan2
- OTX2 | c.*282A>G | 3'UTR (SNP) | VAF 14/88 reads (16%) | called by muse, mutect2, varscan2
- PACSIN1 | c.*715C>T | 3'UTR (SNP) | VAF 38/87 reads (44%) | called by muse, mutect2, varscan2
- PHF24 | c.*1519C>T | 3'UTR (SNP) | VAF 60/100 reads (60%) | called by muse, mutect2
- PPY2P | n.624C>T | RNA (SNP) | VAF 85/175 reads (49%) | called by muse, mutect2, varscan2
- PRRT4 | c.-17C>T | 5'UTR (SNP) | VAF 21/34 reads (62%) | catalogued as rs752779916; called by muse, mutect2, varscan2
- RBM28 | c.-52T>C | 5'UTR (SNP) | VAF 12/44 reads (27%) | called by muse, mutect2, varscan2
- ROPN1B | c.116+1397T>C | Intron (SNP) | VAF 220/694 reads (32%) | called by muse, mutect2, varscan2
- SH2D6 | n.583C>T | RNA (SNP) | VAF 63/108 reads (58%) | catalogued as COSV61064125; called by muse, mutect2, varscan2
- SLC5A10 | c.982+1981G>A | Intron (SNP) | VAF 48/84 reads (57%) | called by muse, mutect2, varscan2
- SLC6A13 | c.202+25C>A | Intron (SNP) | VAF 69/154 reads (45%) | called by muse, mutect2, varscan2
- SRGAP3 | c.*559T>C | 3'UTR (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2, varscan2
- SYT4 | c.*1050G>A | 3'UTR (SNP) | VAF 12/39 reads (31%) | catalogued as rs1433202025; called by muse, mutect2, varscan2
- TCF21 | c.*1635T>C | 3'UTR (SNP) | VAF 38/75 reads (51%) | called by muse, mutect2, varscan2
- TNFRSF19 | chr13:23674141 G>C | 3'Flank (SNP) | VAF 43/98 reads (44%) | called by muse, mutect2, varscan2
- TRAF6 | chr11:36487937 A>C | 3'Flank (SNP) | VAF 14/91 reads (15%) | called by muse, mutect2, varscan2
- TTC39A | c.1161+1674C>G | Intron (SNP) | VAF 7/25 reads (28%) | called by muse, mutect2, varscan2
- TUBB4AP1 | n.484C>A | RNA (SNP) | VAF 26/60 reads (43%) | called by muse, mutect2, varscan2
- UGGT1 | c.*1102T>C | 3'UTR (SNP) | VAF 54/114 reads (47%) | called by muse, mutect2, varscan2
- UNC13B | c.-197G>A | 5'UTR (SNP) | VAF 27/60 reads (45%) | catalogued as rs1295324930; called by muse, mutect2, varscan2
- VASH1 | c.-510C>T | 5'UTR (SNP) | VAF 35/52 reads (67%) | catalogued as rs1013460296; called by muse, mutect2, varscan2
- VCPIP1 | c.*4690C>T | 3'UTR (SNP) | VAF 9/17 reads (53%) | catalogued as rs958477539; called by muse, mutect2, varscan2
- ZNF22 | c.*661dup | 3'UTR (INS) | VAF 38/71 reads (54%) | catalogued as rs775715105; called by mutect2, varscan2
- ZNF398 | c.*855G>A | 3'UTR (SNP) | VAF 29/50 reads (58%) | called by muse, mutect2, varscan2
